Somatic mutation profile of tumor specimen TCGA-VQ-AA6A-01A (aliquot TCGA-VQ-AA6A-01A-11D-A410-08) from TCGA case TCGA-VQ-AA6A, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 56.8 years (20,764 days).
Specimen TCGA-VQ-AA6A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00a568ff-501b-4d20-9500-353c70387132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6A-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6A-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8cb678b-50df-4a37-a87f-acaa26724109

The open-access MAF lists 104 somatic variants for this specimen: 76 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 24, Frame Shift Del 4, Nonsense Mutation 3, RNA 2, In Frame Ins 1, Splice Region 1, Frame Shift Ins 1, Intron 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNA1 | c.601G>A p.V201M (on ENST00000261007 / NM_001039523.3; = p.V176M on NM_000079.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs137852799, CM970303; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 28/32 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100217490; called by muse, mutect2, varscan2
- ACRV1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 14/179 reads (8%) | catalogued as COSV100223597; called by muse, mutect2
- ALG10 | c.1196T>A p.F399Y | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as COSV99847961, COSV99848245; called by muse, mutect2, varscan2
- ALK | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs531490912, COSV66571374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372130536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANOS1 | c.1395A>C p.E465D | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99391116; called by muse, mutect2, varscan2
- BCAR1 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327850193, COSV99366934; called by muse, mutect2, varscan2
- BCORL1 | c.3676C>G p.R1226G | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99500156; called by muse, mutect2, varscan2
- BIRC6 | c.13004G>C p.S4335T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV101428484; called by muse, mutect2
- CACNA2D3 | c.2738G>A p.S913N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as COSV99875230; called by muse, mutect2, varscan2
- CCDC15 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV100777012; called by muse, mutect2, varscan2
- CD33 | c.925-2A>C p.X309_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV51801109, COSV51805320; called by muse, mutect2, varscan2
- CELSR3 | c.6097G>A p.G2033R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99374201; called by muse, mutect2, varscan2
- CMSS1 | c.788T>C p.M263T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV101375603; called by muse, mutect2
- CSAG1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV100756977, COSV63295414; called by muse, mutect2, varscan2
- CSMD3 | c.3155A>C p.K1052T (on ENST00000297405 / NM_001363185.1; = p.K948T on NM_052900.3) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99840205, COSV99846675; called by muse, mutect2, varscan2
- CTSO | c.877A>C p.S293R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.076); catalogued as COSV70808893, COSV70809027; called by muse, mutect2, varscan2
- CYP7B1 | c.1208A>G p.D403G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100042346; called by muse, mutect2, varscan2
- DDX11 | c.2718G>C p.M906I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99299937; called by muse, mutect2, varscan2
- DIO3 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242119269, COSV100832166, COSV99064721; called by muse, mutect2, varscan2
- DOCK2 | c.5257T>C p.F1753L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); catalogued as COSV99913829, COSV99915334; called by muse, mutect2, varscan2
- DOP1B | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1294520725, COSV101215616; called by muse, mutect2, varscan2
- FBN2 | c.1864A>G p.T622A | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99328966; called by muse, mutect2, varscan2
- FOSL2 | c.929G>T p.S310I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1451894398, COSV99268438; called by muse, mutect2, varscan2
- GCKR | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs748126408, COSV53109320; called by muse, mutect2, varscan2
- GPR6 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs766559161, COSV51574227; called by muse, mutect2, varscan2
- GRM5 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1254022905, COSV59588107; called by muse, mutect2, varscan2
- GUCY1A1 | c.853A>C p.T285P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99638141; called by muse, mutect2, varscan2
- GYS1 | c.913C>G p.Q305E | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as COSV99620921; called by muse, mutect2
- HRNR | c.3001T>A p.S1001T | Missense Mutation (SNP) | VAF 168/283 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100913674, COSV64261453; called by muse, mutect2, varscan2
- HUWE1 | c.11213G>A p.R3738H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs782484577, COSV53343609; called by muse, mutect2, varscan2
- IGSF3 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100604914; called by muse, mutect2, varscan2
- KIAA1217 | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs200657746, COSV56812686; called by muse, mutect2, varscan2
- KLHL1 | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV100917699; called by muse, mutect2, varscan2
- MFAP5 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142380998; called by muse, mutect2
- MTMR12 | c.2175G>A p.W725* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99373787; called by muse, mutect2, varscan2
- MUC16 | c.21526C>T p.H7176Y | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV101200494, COSV67495410; called by muse, mutect2, varscan2
- MUC17 | c.8555C>A p.T2852K | Missense Mutation (SNP) | VAF 74/945 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100074224; called by muse, mutect2
- NUAK2 | c.504G>A p.Q168= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100904111, COSV100904173; called by muse, mutect2, varscan2
- NXPE4 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV100970507; called by muse, mutect2, varscan2
- OR2L2 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100824082, COSV63553534; called by muse, mutect2, varscan2
- PHKB | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs374998590; called by muse, mutect2, varscan2
- PRAM1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1027874916, COSV55314232; called by muse, mutect2, varscan2
- PTPRT | c.2645A>C p.K882T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100628821; called by muse, mutect2, varscan2
- RAB38 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 49/298 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760114172, COSV54712089; called by muse, mutect2, varscan2
- RTEL1 | c.3270C>G p.D1090E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99423160; called by muse, mutect2, varscan2
- SALL2 | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100444496; called by muse, mutect2, varscan2
- SDSL | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as rs751291797, COSV100615226; called by muse, varscan2
- SEMA6A | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.448); catalogued as rs1460701034, COSV99963481; called by muse, mutect2, varscan2
- SIPA1L2 | c.669A>T p.K223N | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV99478981; called by muse, mutect2
- SLCO5A1 | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.261); catalogued as rs141622109; called by muse, mutect2, varscan2
- TAAR2 | c.461A>T p.K154I (on ENST00000367931 / NM_001033080.1; = p.K109I on NM_014626.3) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99255707; called by muse, mutect2, varscan2
- TARBP1 | c.1841T>G p.V614G | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99241864; called by muse, mutect2
- TBXT | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs764888773, COSV51617655, COSV99752710; called by muse, mutect2, varscan2
- TDRD5 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676291, COSV99676678; called by muse, mutect2
- TDRD7 | c.2978A>G p.D993G | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100795730; called by muse, mutect2, varscan2
- THG1L | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99180264; called by muse, mutect2, varscan2
- TPM3 | c.568C>T p.R190C (on ENST00000368530 / NM_001364682.1; = p.R153C on NM_153649.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs142738030, COSV55137260; called by muse, mutect2, varscan2
- TRANK1 | c.6436G>A p.G2146R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as rs1306393914, COSV100083752; called by muse, mutect2, varscan2
- TRHDE | c.2887A>C p.S963R | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); catalogued as COSV53866099, COSV99671625; called by muse, mutect2, varscan2
- TTN | c.71702T>G p.V23901G (on ENST00000591111; = p.V16477G on NM_003319.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | PolyPhen probably damaging (0.974); catalogued as COSV100620740; called by muse, mutect2, varscan2
- VEGFC | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99710027; called by muse, mutect2
- ZNF441 | c.1828A>G p.T610A | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV100777441; called by muse, mutect2, varscan2
- ZNF493 | c.1627A>T p.T543S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV100828785; called by muse, mutect2, varscan2
- ZNF501 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.405); catalogued as COSV101247121; called by muse, mutect2, varscan2
- ZNF583 | c.763T>G p.L255V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99382229; called by muse, mutect2, varscan2
- ZNF664 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs923562460, COSV100544527; called by muse, mutect2, varscan2
- CCT8L2 | c.1654del p.I552Sfs*4 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, varscan2
- IGF2R | c.405del p.T137Pfs*8 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | called by mutect2, pindel, varscan2
- KCNS1 | c.1521_1524del p.Q508Lfs*4 | Frame Shift Del (DEL) | VAF 36/247 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.2124C>G p.S708R | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- MYO1H | c.1974_1989del p.W659Gfs*10 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel
- TMEM165 | c.940dup p.S314Ffs*8 | Frame Shift Ins (INS) | VAF 28/140 reads (20%) | called by mutect2, pindel, varscan2
- TXNIP | c.799_801dup p.C267dup | In Frame Ins (INS) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- ABCC6 | c.1806C>T p.V602= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99229164; called by muse, mutect2, varscan2
- ADAMTS16 | c.2445T>G p.T815= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV56976480, COSV56976826; called by muse, mutect2, varscan2
- BBX | c.1398A>G p.K466= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100361962, COSV57892203; called by muse, mutect2, varscan2
- BFSP1 | c.1698C>T p.D566= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as rs372180196; called by muse, mutect2, varscan2
- CD14 | c.546G>A p.S182= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100117578; called by muse, mutect2
- CLEC12B | c.600G>A p.S200= | Silent (SNP) | VAF 94/127 reads (74%) | catalogued as rs373680539; called by muse, mutect2, varscan2
- DIDO1 | c.3993C>G p.S1331= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV99826435; called by muse, mutect2, varscan2
- DNAAF5 | c.1837C>T p.L613= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1192480227, COSV99860033; called by muse, mutect2
- FOSL2 | c.930C>T p.S310= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs141121352; called by muse, mutect2, varscan2
- GHSR | c.117C>T p.P39= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs776496820, COSV53840268; called by muse, mutect2, varscan2
- GRM1 | c.2502G>A p.K834= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV51123582, COSV51143207; called by muse, mutect2
- H2BC15 | c.144G>A p.Q48= | Silent (SNP) | VAF 43/263 reads (16%) | catalogued as rs1029579350, COSV100357033; called by muse, mutect2, varscan2
- KCTD16 | c.807A>T p.S269= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV101568842; called by muse, mutect2, varscan2
- MMP16 | c.1638A>T p.P546= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99689356; called by muse, mutect2, varscan2
- MUC16 | c.2970T>G p.T990= | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as COSV67465919; called by muse, mutect2
- NT5C1A | c.72C>T p.A24= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99348550; called by muse, mutect2
- NUP58 | c.1011T>C p.H337= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as COSV101098834, COSV67752208; called by muse, mutect2
- OR4F5 | c.405C>T p.V135= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as rs1216991068, COSV100633198; called by muse, mutect2, varscan2
- OR5D18 | c.579T>G p.T193= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV61738404; called by muse, mutect2, varscan2
- PTPRZ1 | c.5617A>C p.R1873= | Silent (SNP) | VAF 9/240 reads (4%) | catalogued as COSV66439161; called by muse, mutect2
- SYNE1 | c.2304G>A p.K768= (on ENST00000367255 / NM_182961.4; = p.K775= on NM_033071.3) | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV99571797; called by muse, mutect2, varscan2
- TTBK1 | c.1242C>T p.I414= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs745953438, COSV99445077, COSV99445724; called by muse, mutect2, varscan2
- URAD | c.105G>A p.Q35= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100229610; called by muse, mutect2, varscan2
- VCAN | c.9291G>A p.P3097= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as rs375652154; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- BMP1 | c.2107+1720C>T | Intron (SNP) | VAF 31/65 reads (48%) | catalogued as rs528835024, COSV100109838; called by muse, mutect2, varscan2
- IGKV1-13 | n.310A>C | RNA (SNP) | VAF 15/330 reads (5%) | called by muse, mutect2
- SFTA3 | n.903C>T | RNA (SNP) | VAF 36/122 reads (30%) | catalogued as rs200427110, COSV69488807; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827756 A>T | 3'Flank (SNP) | VAF 37/40 reads (93%) | catalogued as COSV100157966; called by muse, mutect2, varscan2
